CCDI case PBCBAH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d36f9e61-4f18-44c6-acd6-854e37b74706

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,226 days).

Biospecimens (3 samples)
- Sample 0DMUXI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMUY5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMUZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
